Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7897, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7897-01A (Primary Tumor).

[page 1 of 3]
HISTOPATHOLOGY REPORT

ORIGINAL REPORT

SPECIMEN:

- A. Gallbladder.
- B. Node of importance.
- C. Whipple's specimen.

CLINICAL HISTORY:

Pancreatic cancer.

DIAGNOSIS:

- A. GALLBLADDER, CHOLECYSTECTOMY:
- CHRONIC CHOLECYSTITIS.

- B. NODE OF IMPORTANCE, BIOPSY:
- METASTATIC PANCREATIC ADENOCARCINOMA.

- C. DUODENUM AND HEAD OF PANCREAS, WHIPPLE'S SURGERY:
- MODERATELY DIFFERENTIATED INFILTRATING DUCTAL ADENOCARCINOMA.
- MAXIMUM DIAMETER 3.5 CM, WITH FOCAL EXTRAPANCREATIC CANCER ADJACENT TO PYLORIC LYMPH NODES, ABUTTING ON PAINTED RESECTION MARGIN.
- PANCREATIC INTRAEPITHELIAL NEOPLASIA (PANIN 1B/2) LOCATED AT THE NECK RESECTION MARGIN IN LARGER PANCREATIC DUCTS.
- 2 OF 17 PERIPANCREATIC LYMPH NODES POSITIVE FOR METASTATIC ADENOCARCINOMA.
- INCIDENTAL PANCREATIC HAMARTOMA/HETEROTOPIA IN DUODENAL WALL.

FINAL

[page 2 of 3]
HISTOPATHOLOGY REPORT

GROSS DESCRIPTION:

A. The specimen consists of a 7.0 x 3.2 x 1.5 cm gallbladder with a grey congested serosa. The thickness of the wall ranges from 0.2 to 0.3 cm. The mucosal surface is green and velvety. No stones are identified. The cystic duct is patent. Three representative sections are submitted in cassette A.

B. The specimen consists of an irregular fragment of soft tissue measuring 1.1 x 1.0 x 0.3 cm. Bisected and submitted in toto in cassette B.

C. The specimen consists of a 21.0 cm of duodenum with a proximal segment of pancreas measuring 4.5 x 4.6 x 2.5 cm. The common bile duct is patent and its resection margin is taken enface. There is a 3.5 x 1.2 x 2.6 cm firm mass occupying all the tissue located above the common bile duct. This mass is located at 0.2 cm from the surface in contact with the mesenteric blood vessels and 0.4 cm from the anterior surface of the pancreas. Located at the mucosal surface at 3.8 cm and 7.4 cm from the proximal resection, there are two yellow nodules measuring 0.3 cm and 0.4 cm respectively. Representative sections are submitted as follows:

- C1. common bile duct margin enface
- C2. pancreatic distal margin enface
- C3. proximal resection margin (stomach)
- C4. distal resection margin (duodenum)
- C5-7. uncinate process, blood vessels, and distal margins (black, blue and orange colors respectively)
- C8-10. tumor and duodenal mucosa
- C11. preserved pancreatic tissue and preserved duodenum mucosa
- C12. yellow nodular lesions at the duodenal mucosa
- C13. distal stomach lymph nodes
- C14-15. common bile duct area lymph nodes
- C16. pancreatic head lymph nodes
- C17. duodenal lymph node, trisected
- C18-20. duodenal lymph nodes, uncut

MICROSCOPIC DESCRIPTION:

The slides from specimen C show a malignant neoplasm composed by a proliferation of large epithelial cells with hyperchromatic, irregular nuclei forming primitive ductal structures surrounded by a dense, collagenized

FINAL

[page 3 of 3]
HISTOPATHOLOGY REPORT

MICROSCOPIC DESCRIPTION:

stroma. The uncinate and other main resection margins are clear of malignant cells but there is extranodal invasive carcinoma around the pyloric nodes that touches the painted outer surface of the specimen. Two of the pyloric nodes have metastatic cancer, 15 other nodes are negative. The resection margin at the neck of the pancreas is clear of carcinoma, but there are some atypical changes compatible with PAN IN 1B and 2 present in the pancreatic duct at this margin.

FINAL

Source: NCI Genomic Data Commons file b3400384-3192-4dff-ae57-d98d58b5082e (TCGA-IB-7897.4C894664-B029-462A-9EF2-A7C859A11272.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).